Somatic mutation profile of tumor specimen TCGA-IQ-A6SH-01A (aliquot TCGA-IQ-A6SH-01A-12D-A34J-08) from TCGA case TCGA-IQ-A6SH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 55.1 years (20,109 days).
Specimen TCGA-IQ-A6SH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b03d80b-e574-4ea8-b9d6-097a037263a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A6SH-10A (Blood Derived Normal), aliquot TCGA-IQ-A6SH-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e454bd01-00cf-40c1-b29d-b40029d8ee28

The open-access MAF lists 84 somatic variants for this specimen: 62 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 18, Nonsense Mutation 4, 3'UTR 2, In Frame Del 2, Frame Shift Ins 2, RNA 1, Splice Region 1, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 42/77 reads (55%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10582C>T p.Q3528* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV101446773; called by muse, mutect2, varscan2
- ADGRG4 | c.5174C>T p.S1725F | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs760138235, COSV99794376; called by muse, mutect2, varscan2
- APOL4 | c.691T>C p.S231P (on ENST00000352371 / NM_145660.2; = p.S228P on NM_030643.4) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100274050; called by muse, mutect2, varscan2
- ATP7B | c.3446G>T p.G1149V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM081179, CM110342, COSV99666047; called by muse, mutect2, varscan2
- BPIFB2 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs577746368, COSV50066075; called by muse, mutect2, varscan2
- CALB1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 14/389 reads (4%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.501); catalogued as COSV99617935; called by muse, mutect2
- CDK11B | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1059815; called by muse, mutect2, varscan2
- CDKN2A | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100445248, COSV58687900, COSV58696860, COSV58723899; called by muse, mutect2, varscan2
- CHMP3 | c.115A>G p.R39G | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV99806526; called by muse, mutect2, varscan2
- CHPT1 | c.951G>T p.M317I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV99901578; called by muse, mutect2
- COL11A1 | c.1798C>G p.R600G | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62187830, COSV99071323; called by muse, mutect2, varscan2
- CTNNA2 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.508); catalogued as rs748889262, COSV63569820; called by muse, mutect2, varscan2
- DAAM2 | c.2253G>A p.R751= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99224593; called by muse, mutect2, varscan2
- ESCO1 | c.1415T>A p.I472N | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV99331924; called by muse, mutect2, varscan2
- FAM98A | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV99479036; called by muse, mutect2, varscan2
- FZD10 | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV99969241; called by muse, mutect2, varscan2
- GRID1 | c.2500_2501insA p.V834Dfs*53 | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | catalogued as COSV100021969; called by mutect2, pindel, varscan2
- IFNW1 | c.136A>T p.R46* | Nonsense Mutation (SNP) | VAF 109/227 reads (48%) | catalogued as COSV101207601; called by muse, mutect2, varscan2
- IKBKE | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396141437, COSV100898086; called by muse, mutect2
- IRX2 | c.804_815del p.D268_E271del | In Frame Del (DEL) | VAF 12/104 reads (12%) | catalogued as rs759898376; called by mutect2, varscan2
- ITPR2 | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377598368; called by muse, mutect2
- JMJD1C | c.5195G>A p.R1732Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs957145359, COSV100550135; called by muse, mutect2, varscan2
- KAT6A | c.3776A>G p.N1259S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV99704405; called by muse, mutect2, varscan2
- KRT80 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs200315755, COSV100502491; called by muse, mutect2, varscan2
- LHFPL1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100914422; called by muse, mutect2, varscan2
- LIG1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs752805843, COSV99618504; called by muse, mutect2, varscan2
- MACF1 | c.4966A>G p.I1656V | Missense Mutation (SNP) | VAF 36/171 reads (21%) | catalogued as COSV99241232; called by muse, mutect2, varscan2
- MAGEB18 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV100305293; called by muse, mutect2
- MAN2A2 | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs535498138, COSV100847751; called by muse, mutect2, varscan2
- MGAT5 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV99924087; called by muse, mutect2, varscan2
- MOSPD3 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770930212, COSV56157874; called by muse, mutect2, varscan2
- MROH2B | c.3304A>G p.T1102A | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101270478; called by muse, mutect2
- NFXL1 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as rs918388133, COSV67433050; called by muse, mutect2
- OR5L2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV101004246, COSV65724932; called by muse, mutect2, varscan2
- PCDHA7 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs368032433, COSV65338759; called by muse, mutect2, varscan2
- PCLO | c.9062C>T p.T3021I | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100427491, COSV100437244; called by muse, mutect2, varscan2
- PCNT | c.1937-1G>C p.X646_splice | Splice Site (SNP) | VAF 9/90 reads (10%) | catalogued as rs774995221, CS080727, COSV100855052; called by muse, mutect2
- PDCD10 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV101208502; called by muse, mutect2, varscan2
- PDE1C | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV100371027; called by muse, mutect2, varscan2
- PDK4 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs893649784, COSV99138733; called by muse, mutect2
- PLEKHA7 | c.2644T>A p.F882I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.343); catalogued as COSV100261824, COSV100261829; called by muse, mutect2
- PLXNA4 | c.571G>C p.G191R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV58119810; called by muse, mutect2
- POM121L12 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs775755313, COSV68694032; called by muse, mutect2, varscan2
- RYR2 | c.9368T>C p.L3123S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100767932; called by muse, mutect2, varscan2
- SACS | c.12405A>T p.K4135N | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV101207170; called by muse, mutect2
- SALL1 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.085); catalogued as rs1490389639, COSV99171559; called by muse, mutect2, varscan2
- SETD7 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99918344; called by muse, mutect2, varscan2
- SLC9C1 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99997322; called by muse, mutect2, varscan2
- SYCP1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101050756; called by muse, mutect2, varscan2
- SYTL5 | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99936893; called by muse, mutect2, varscan2
- TMOD4 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99765876; called by muse, mutect2, varscan2
- TTN | c.33208G>A p.E11070K (on ENST00000591111; = p.E10143K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/234 reads (12%) | PolyPhen benign (0.053); catalogued as COSV100594499; called by muse, mutect2, varscan2
- ZBTB11 | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100465152; called by muse, mutect2, varscan2
- ZNF700 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.856); catalogued as COSV99583260; called by muse, mutect2, varscan2
- ZPLD1 | c.719C>T p.S240L (on ENST00000466937 / NM_001329788.1; = p.S256L on NM_175056.2) | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100082918; called by muse, mutect2, varscan2
- BLK | c.1339_1348del p.N447Afs*134 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- IGHV3-64 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KBTBD6 | c.2012_2014del p.V671del | In Frame Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.791T>G p.L264R | Missense Mutation (SNP) | VAF 110/223 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- PPL | c.185dup p.R63Sfs*4 | Frame Shift Ins (INS) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- ACTG1 | c.252G>A p.K84= | Silent (SNP) | VAF 93/160 reads (58%) | catalogued as rs139059365, COSV59511770; called by muse, mutect2, varscan2
- ADAMTS8 | c.2211G>A p.T737= | Silent (SNP) | VAF 37/186 reads (20%) | catalogued as rs1164774596, COSV99960365, COSV99961522; called by muse, mutect2, varscan2
- ATP8A1 | c.1080G>A p.L360= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100044994, COSV52532942; called by muse, mutect2, varscan2
- CASKIN1 | c.714G>A p.R238= | Silent (SNP) | VAF 58/162 reads (36%) | catalogued as COSV100623813; called by muse, mutect2, varscan2
- CHRNA4 | c.1683G>A p.S561= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs750265666, COSV100937339; ClinVar: likely benign; called by muse, mutect2
- EYA4 | c.225T>C p.V75= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100765190; called by muse, mutect2, varscan2
- FGF23 | c.549C>T p.D183= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs369808475; called by muse, mutect2
- JAG2 | c.3492G>A p.A1164= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs375025132; called by muse, mutect2, varscan2
- MMS22L | c.2745C>T p.S915= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs139062728; called by muse, mutect2, varscan2
- OR2D2 | c.504C>T p.Y168= | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as COSV100203721; called by muse, mutect2, varscan2
- OR2T4 | c.609C>T p.S203= | Silent (SNP) | VAF 91/286 reads (32%) | catalogued as COSV63543838; called by muse, mutect2, varscan2
- PAX2 | c.1101C>T p.F367= (on ENST00000428433 / NM_003987.5; = p.F344= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV62293176; called by muse, mutect2, varscan2
- PDILT | c.1632C>T p.Y544= | Silent (SNP) | VAF 119/333 reads (36%) | catalogued as rs374255958, COSV56701088; called by muse, mutect2, varscan2
- POM121L12 | c.117G>A p.T39= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs773409594, COSV101374843; called by muse, mutect2, varscan2
- SLC8A1 | c.1227C>A p.I409= | Silent (SNP) | VAF 27/232 reads (12%) | catalogued as COSV60496656; called by muse, mutect2, varscan2
- SSR2 | c.25T>C p.L9= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99828516; called by muse, mutect2, varscan2
- TSSK6 | c.375C>T p.Y125= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV53064165, COSV99388904; called by muse, mutect2, varscan2
- ZNF804A | c.1893G>A p.G631= | Silent (SNP) | VAF 105/270 reads (39%) | catalogued as COSV100166447; called by muse, mutect2, varscan2
- ASPSCR1 | c.1354-1293G>A | Intron (SNP) | VAF 21/124 reads (17%) | catalogued as rs776306980, COSV100142341; called by muse, mutect2, varscan2
- ATXN2L | c.*479C>T | 3'UTR (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100293573; called by muse, mutect2, varscan2
- GPR17 | c.*2C>T | 3'UTR (SNP) | VAF 20/89 reads (22%) | catalogued as rs372407392; called by muse, mutect2, varscan2
- SLC66A1L | n.306C>T | RNA (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100396327; called by muse, mutect2, varscan2
